Gene-level copy-number profile of tumor specimen TCGA-78-7150-01A from TCGA case TCGA-78-7150, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.9 years (21,891 days).
Specimen TCGA-78-7150-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.81e5055c-615b-4633-a373-c12173a75440.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7150-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f9f14054-bf3c-4308-9b2c-ff55e7935c79

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 104; copy number 1: 1,127; copy number 2: 17,376; copy number 3: 25,950; copy number 4: 10,112; copy number 5: 4,211; copy number 6: 551; copy number 7: 258; copy number 8: 29; copy number 9: 36; copy number 10: 48; copy number 31: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7150-01A-21D-2035-01): tumor purity 0.46, ploidy 2.99, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 104 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:10,777,357–11,436,244, 6 genes: AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1.
- chr9:17,579,066–17,797,124, 2 genes (within-gene range 0–1): SH3GL2, PABPC1P11.
- chr9:19,957,394–22,455,740, 68 genes (broad region; genes not listed).
- chr9:25,579,657–26,118,408, 5 genes: AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr16:89,818,179–90,222,851, 22 genes: SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr18:66,946,116–66,946,222, 1 gene: RNU6-1037P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 383 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:102,967,408–102,984,429, 1 gene, copy number 8: LINC01935.
- chr4:53,377,641–55,161,880, 33 genes, copy number 7–9: FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2.
- chr6:43,995,723–44,257,890, 14 genes, copy number 7: AL109615.3, C6orf223, AL109615.2, AL109615.1, AL109615.4, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647.
- chr6:63,193,072–63,779,336, 16 genes, copy number 9: AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 9: AL354719.1, SCAT8, GCNT1P4.
- chr9:32,293,558–32,676,520, 12 genes, copy number 31: RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1.
- chr11:77,034,398–78,582,156, 45 genes, copy number 10: B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr11:78,749,250–78,756,480, 1 gene, copy number 10: AP002768.1.
- chr12:66,767–7,479,897, 228 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr16:54,845,189–54,929,189, 2 genes, copy number 10 (within-gene range 6–10): CRNDE, AC106742.1.
- chr18:23,957,754–24,986,980, 28 genes, copy number 8 (within-gene range 6–8): AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1.

Autosomal genes at a single copy (total copy number 1): 1,127. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
